Somatic mutation profile of tumor specimen TCGA-24-1413-01A (aliquot TCGA-24-1413-01A-01W-0494-09) from TCGA case TCGA-24-1413, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.6 years (18,846 days).
Specimen TCGA-24-1413-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f4a3a82-03ce-4488-9a67-6e38d8641b9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1413-10A (Blood Derived Normal), aliquot TCGA-24-1413-10A-01W-0495-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede70b75-2d1f-4375-a279-3b9ce7899634

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 2, Frame Shift Ins 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 110/116 reads (95%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC134980.2 | c.848A>T p.N283I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs768590655, COSV60908158; called by mutect2, varscan2
- ACP3 | c.1115G>T p.C372F | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60487139; called by muse, mutect2, varscan2
- ADH1C | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV72892961; called by muse, mutect2, varscan2
- ADHFE1 | c.425C>A p.T142N | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52556765; called by muse, mutect2, varscan2
- ADIPOQ | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 240/551 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57859443; called by muse, mutect2, varscan2
- ATAD5 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV58976120; called by muse, mutect2, varscan2
- BAZ1A | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 168/360 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62409022, COSV62410838; called by muse, varscan2
- CACNA2D4 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54953656; called by muse, mutect2
- CCR9 | c.968G>T p.R323I (on ENST00000357632 / NM_031200.3; = p.R311I on NM_006641.4) | Missense Mutation (SNP) | VAF 284/492 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62940065, COSV62940450; called by muse, mutect2, varscan2
- CNTN4 | c.2054C>A p.P685H | Missense Mutation (SNP) | VAF 97/637 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61875648; called by muse, mutect2, varscan2
- DAW1 | c.914A>T p.E305V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100005761; called by muse, mutect2
- DLX6 | c.804dup p.N269Qfs*59 | Frame Shift Ins (INS) | VAF 8/84 reads (10%) | catalogued as rs1469158094; called by mutect2, pindel
- DNAH5 | c.4359T>A p.C1453* | Nonsense Mutation (SNP) | VAF 44/91 reads (48%) | catalogued as COSV54235898; called by muse, mutect2
- DNAH5 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 74/305 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1302047281, COSV54235906; called by muse, mutect2, varscan2
- EXO1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV62218241; called by muse, mutect2, varscan2
- GPHB5 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as COSV58486390; called by muse, mutect2, varscan2
- GRID1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs201908927, COSV60015721; called by muse, mutect2, varscan2
- HCN3 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs746241919, COSV64233551; called by muse, mutect2, varscan2
- IFNA1 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs375932242; called by muse, mutect2, varscan2
- IGKV4-1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs371960591; called by muse, mutect2, varscan2
- IL4R | c.2359G>C p.E787Q | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1468023307, COSV99404581; called by muse, mutect2
- ILKAP | c.142T>C p.F48L | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV54518805; called by muse, mutect2, varscan2
- KBTBD8 | c.1591C>G p.Q531E | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55129787, COSV99805170; called by muse, mutect2, varscan2
- MRTFB | c.1207T>G p.L403V | Missense Mutation (SNP) | VAF 183/379 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV57959146; called by muse, mutect2, varscan2
- MYH10 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 52/59 reads (88%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs755114317, COSV52604684; called by muse, mutect2, varscan2
- NARS2 | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV55253166; called by muse, mutect2, varscan2
- PCDHAC2 | c.966dup p.L323Afs*4 | Frame Shift Ins (INS) | VAF 5/35 reads (14%) | catalogued as rs782507143; called by mutect2, pindel
- PCNT | c.9505G>A p.E3169K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100854966; called by muse, mutect2
- PKHD1 | c.4270G>C p.D1424H | Missense Mutation (SNP) | VAF 149/328 reads (45%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.514); catalogued as COSV61883279; called by muse, mutect2, varscan2
- RHOF | c.582C>G p.S194R | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV57363489; called by muse, mutect2, varscan2
- SFXN4 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV100340904; called by muse, mutect2
- SLC22A25 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 150/288 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs775834936, COSV60597046; called by muse, mutect2, varscan2
- SLC26A9 | c.1104G>C p.E368D | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100535904; called by muse, mutect2, varscan2
- SLC27A5 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV99564092; called by muse, mutect2, varscan2
- SLC4A8 | c.1874A>G p.H625R | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100176341; called by muse, mutect2
- SSBP1 | c.167T>G p.I56R | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV54681525; called by muse, mutect2, varscan2
- TPTE | c.758C>A p.S253Y (on ENST00000618007 / NM_199261.4; = p.S235Y on NM_199259.4) | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs778158530; called by muse, mutect2, varscan2
- TRIM4 | c.1376T>C p.F459S | Missense Mutation (SNP) | VAF 268/622 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62469775; called by muse, varscan2
- UGT2A1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs374804650; called by muse, mutect2, varscan2
- UTP25 | c.1603G>C p.G535R | Missense Mutation (SNP) | VAF 113/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101504715; called by muse, mutect2, varscan2
- UTP25 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101504716; called by muse, mutect2, varscan2
- KIAA1755 | c.434del p.F145Sfs*23 | Frame Shift Del (DEL) | VAF 39/313 reads (12%) | called by mutect2, pindel, varscan2
- AL441992.2 | c.1395G>A p.K465= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV100223328; called by muse, mutect2
- CAMSAP3 | c.276G>T p.L92= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV99349588; called by muse, mutect2, varscan2
- EPHA3 | c.2667G>A p.K889= | Silent (SNP) | VAF 74/174 reads (43%) | catalogued as COSV100341795, COSV60713346, COSV60728845; called by muse, mutect2, varscan2
- KIR2DL3 | c.267C>A p.P89= | Silent (SNP) | VAF 1035/1954 reads (53%) | called by muse, mutect2, varscan2
- PADI4 | c.1710C>T p.L570= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV64924324; called by muse, mutect2, varscan2
- PPM1H | c.1086C>T p.T362= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs754210696, COSV57376211; called by muse, mutect2, varscan2
- SFXN4 | c.663C>T p.S221= | Silent (SNP) | VAF 20/352 reads (6%) | catalogued as COSV57459773; called by muse, mutect2
- TCF12 | c.2013G>C p.G671= | Silent (SNP) | VAF 39/269 reads (14%) | catalogued as COSV51011378; called by muse, mutect2, varscan2
- TRPA1 | c.2316T>C p.T772= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV51565467, COSV51565910; called by muse, mutect2, varscan2
- ZNF446 | c.6A>G p.P2= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as rs1482540563, COSV52181340; called by muse, mutect2, varscan2
- TPI1 | c.*233C>T | 3'UTR (SNP) | VAF 35/62 reads (56%) | catalogued as rs1168291422, COSV99222771; called by muse, mutect2, varscan2
